Somatic mutation profile of tumor specimen 0DQS07 from CCDI case PBCFME, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Tissue or organ of origin: Middle lobe, lung; Age at diagnosis: 17.8 years (6,508 days).
Specimen 0DQS07: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42c0fc13-7d33-41de-87e6-8a3b3ec60395.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQS0P (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c92ec757-bbc2-4584-9cbe-67fa51817444

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Missense Mutation 2, Nonsense Mutation 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDM7A | c.912A>G p.I304M | Missense Mutation (SNP) | VAF 94/754 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50098002; called by muse, varscan2
- GLG1 | c.642T>G p.Y214* | Nonsense Mutation (SNP) | VAF 212/636 reads (33%) | called by muse, varscan2
- KDM2A | c.606G>A p.M202I | Missense Mutation (SNP) | VAF 102/800 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, varscan2
- PREX2 | c.4123C>T p.Q1375* | Nonsense Mutation (SNP) | VAF 138/678 reads (20%) | called by muse, varscan2
- CDH18 | c.237C>T p.S79= | Silent (SNP) | VAF 72/546 reads (13%) | catalogued as COSV56909903; called by muse, varscan2
- DRC7 | c.2127G>A p.A709= | Silent (SNP) | VAF 58/495 reads (12%) | catalogued as rs372369779; called by muse, varscan2
- FHOD1 | c.-59G>A | 5'UTR (SNP) | VAF 22/134 reads (16%) | called by muse, varscan2
